FM case AD7050 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/986b4091-ed08-4d7a-b556-3472009d7f39

Male, 64.8 years: Carcinoma, NOS (ICD-O-3 8010/3); specimen biopsied or resected from the abdomen. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Tumor.
